Somatic mutation profile of tumor specimen MMRF_2384_1_BM_CD138pos (aliquot MMRF_2384_1_BM_CD138pos_T1_KHS5U_L11239) from MMRF case MMRF_2384, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,882 days).
Specimen MMRF_2384_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a11c15a-f21f-4fad-b848-17ff9b0fd48d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2384_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2384_1_PB_WBC_C3_KHS5U_L11240; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33da8189-13e3-41a2-a66a-c3544b3d3527

The open-access MAF lists 52 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 15, Silent 8, Intron 3, 5'Flank 2, 5'UTR 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPH | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs1284415051; called by muse, mutect2, varscan2
- C8orf74 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV58755432, COSV58755514; called by muse, mutect2, varscan2
- CSMD3 | c.7229A>G p.D2410G (on ENST00000297405 / NM_001363185.1; = p.D2306G on NM_052900.3) | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs747417151; called by muse, mutect2, varscan2
- CTTNBP2 | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs746241505, COSV50413112; called by muse, mutect2, varscan2
- EPHA10 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781176065, COSV57627478; called by muse, mutect2, varscan2
- H2AC14 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as rs1561925478; called by muse, mutect2, varscan2
- MKI67 | c.6658G>A p.A2220T | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as rs759944056; called by muse, mutect2, varscan2
- PRKCQ | c.1445+1G>A p.X482_splice | Splice Site (SNP) | VAF 65/198 reads (33%) | catalogued as rs1190765193, COSV54111433; called by muse, mutect2, varscan2
- RBFOX1 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 28/119 reads (24%) | catalogued as COSV60952754; called by muse, varscan2
- SPHKAP | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs1397800761, COSV100763628; called by muse, mutect2, varscan2
- TYR | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs149684917, COSV99634974; called by muse, mutect2, varscan2
- AKAP4 | c.1795A>C p.K599Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ALG3 | c.125C>G p.T42R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- BRSK1 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- DLGAP1 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MPDZ | c.1669A>T p.S557C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- OR2B3 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR5D13 | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PHEX | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNRPA | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ZBTB5 | c.1945del p.R649Gfs*52 | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | called by mutect2, pindel, varscan2
- ZC2HC1C | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ANKRD17 | c.5994T>C p.L1998= | Silent (SNP) | VAF 7/176 reads (4%) | called by muse, mutect2
- ARHGAP18 | c.33A>G p.V11= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2
- DGKG | c.2199C>T p.C733= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs546201700, COSV53974226, COSV99404505; called by muse, mutect2, varscan2
- ERMP1 | c.921A>G p.K307= | Silent (SNP) | VAF 80/292 reads (27%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.339G>T p.T113= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs1441146570; called by muse, mutect2, varscan2
- OCM | c.12G>A p.T4= | Silent (SNP) | VAF 66/308 reads (21%) | catalogued as rs373831481, COSV99631496; called by muse, mutect2, varscan2
- TTK | c.1503T>A p.T501= | Silent (SNP) | VAF 76/317 reads (24%) | called by muse, mutect2, varscan2
- USP20 | c.2439G>A p.S813= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs781264175, COSV59619579; called by muse, mutect2, varscan2
- ABHD5 | c.-90G>A | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs1299153040; called by muse, mutect2, varscan2
- ANAPC7 | c.*754G>T | 3'UTR (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- CA2 | c.444+28del | Intron (DEL) | VAF 53/171 reads (31%) | called by mutect2, varscan2
- CALN1 | c.*7286T>G | 3'UTR (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- CCR4 | c.*500A>G | 3'UTR (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- DAB2 | c.330+10C>T | Intron (SNP) | VAF 8/239 reads (3%) | called by muse, mutect2
- DAW1 | c.*215C>T | 3'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- DPP10 | c.*2468G>A | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- ENPP6 | c.*1310C>A | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- EVC | c.*969G>T | 3'UTR (SNP) | VAF 88/316 reads (28%) | called by muse, mutect2, varscan2
- GAS1 | c.*460dup | 3'UTR (INS) | VAF 20/114 reads (18%) | catalogued as rs995300177; called by mutect2, varscan2
- GIMAP8 | c.*1008G>T | 3'UTR (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- H6PD | c.*4376G>A | 3'UTR (SNP) | VAF 113/404 reads (28%) | catalogued as rs751158571; called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863437 A>C | 5'Flank (SNP) | VAF 8/22 reads (36%) | catalogued as rs1555384631; called by muse, varscan2
- KDM4C | c.*526T>C | 3'UTR (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- LINC02871 | n.1059A>T | RNA (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- MAPRE2 | c.*1365A>C | 3'UTR (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851158 C>G | 5'Flank (SNP) | VAF 66/243 reads (27%) | called by muse, mutect2, varscan2
- PLD4 | c.*136C>T | 3'UTR (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- RAB7A | c.*70C>T | 3'UTR (SNP) | VAF 166/588 reads (28%) | called by muse, varscan2
- SF3B2 | c.2617-55G>C | Intron (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- SRRM3 | c.*83A>G | 3'UTR (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
